Somatic mutation profile of tumor specimen TCGA-IN-8663-01A (aliquot TCGA-IN-8663-01A-11D-2394-08) from TCGA case TCGA-IN-8663, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 68.9 years (25,172 days).
Specimen TCGA-IN-8663-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffee82e6-3512-4a80-b73d-5960aa751a1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-8663-10A (Blood Derived Normal), aliquot TCGA-IN-8663-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef64abb5-a0bf-4e79-a335-6538f2190a1c

The open-access MAF lists 172 somatic variants for this specimen: 126 protein-altering or splice-affecting, 42 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 42, Nonsense Mutation 5, Frame Shift Ins 3, 3'UTR 2, Splice Site 1, 5'UTR 1, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 31/73 reads (42%) | hotspot (GDC flag); catalogued as CD972119, COSV58683444, COSV58717600; called by muse, mutect2, varscan2
- ERBB2 | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 60/79 reads (76%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs144434331, COSV54062853, COSV54063030; ClinVar: not provided; called by muse, mutect2, varscan2
- MAGI2 | c.1808T>C p.L603P | Missense Mutation (SNP) | VAF 27/63 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62636665, COSV62664406; called by muse, mutect2, varscan2
- AATK | c.1958C>T p.A653V (on ENST00000326724 / NM_001080395.3; = p.A550V on NM_004920.2) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as rs762845072, COSV58364450; called by muse, mutect2, varscan2
- ABL1 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1216325712, COSV59325670; called by muse, mutect2, varscan2
- ACCSL | c.895T>A p.F299I | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66580284; called by muse, mutect2, varscan2
- ADAMTS12 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV61254638; called by muse, mutect2, varscan2
- ADAMTSL5 | c.576C>G p.F192L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV57860151; called by muse, mutect2, varscan2
- ADCY3 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.741); catalogued as rs1464692366, COSV53164752; called by muse, mutect2, varscan2
- AFF2 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 287/303 reads (95%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60655918; called by muse, mutect2, varscan2
- AIFM2 | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as rs770588744, COSV57158713; called by muse, mutect2, varscan2
- ALMS1 | c.7847G>A p.R2616Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0.058); catalogued as rs1191032728, COSV52503745; called by muse, mutect2, varscan2
- ARNT2 | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 111/278 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57582067; called by muse, mutect2, varscan2
- ATG4C | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58603920, COSV58609507; called by muse, mutect2, varscan2
- ATP11B | c.3431G>A p.C1144Y | Missense Mutation (SNP) | VAF 98/213 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1480968650, COSV60026469; called by muse, varscan2
- BCAT1 | c.527A>C p.K176T | Missense Mutation (SNP) | VAF 329/375 reads (88%) | SIFT tolerated (0.4); PolyPhen benign (0.035); catalogued as rs376524284, COSV53907997; called by muse, mutect2, varscan2
- BCHE | c.1672T>G p.L558V | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV52254006; called by muse, mutect2, varscan2
- BRINP3 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs775664699, COSV66514695; called by muse, mutect2, varscan2
- C1QL4 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs898765199, COSV57743239; called by muse, mutect2
- CALR3 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs768015132, COSV54168273; called by muse, mutect2, varscan2
- CAMSAP2 | c.3890G>A p.G1297D (on ENST00000236925 / NM_001297707.2; = p.G1286D on NM_203459.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV52667156; called by muse, mutect2, varscan2
- CDH18 | c.1609T>G p.F537V | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56904308; called by muse, mutect2, varscan2
- CDHR1 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60559791; called by muse, mutect2, varscan2
- CILP | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370038983; called by muse, mutect2, varscan2
- CNBD1 | c.806T>G p.V269G | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.19); PolyPhen benign (0.282); catalogued as COSV73072512; called by muse, mutect2, varscan2
- CSMD3 | c.1598T>G p.F533C (on ENST00000297405 / NM_001363185.1; = p.F429C on NM_052900.3) | Missense Mutation (SNP) | VAF 85/159 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52111459; called by muse, mutect2, varscan2
- CUBN | c.7144T>C p.F2382L | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.058); catalogued as COSV64708805; called by muse, mutect2, varscan2
- CUBN | c.466dup p.C156Lfs*15 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | catalogued as rs755846379; called by mutect2, varscan2
- CWC22 | c.1888T>G p.F630V | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55426930; called by muse, mutect2, varscan2
- CXXC1 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.992); catalogued as rs772822946, COSV53273351; called by muse, mutect2, varscan2
- DBH | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs755891058, COSV55039865; called by muse, mutect2, varscan2
- DCC | c.3404C>T p.T1135I | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.101); catalogued as rs751325930, COSV71426914; called by muse, mutect2, varscan2
- DNAH2 | c.6334T>G p.F2112V | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV66716842; called by muse, mutect2, varscan2
- DNAH8 | c.5867G>A p.R1956H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139579198, COSV59427962; called by muse, mutect2, varscan2
- DPYS | c.1171A>G p.R391G | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV59826759, COSV59826868, COSV59826998; called by muse, mutect2, varscan2
- ELOA2 | c.1832T>C p.L611P | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755404558, COSV55294215; called by muse, mutect2, varscan2
- EP400 | c.7886C>T p.T2629M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1387041475, COSV57764066; called by muse, mutect2
- ERBB2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54064314; called by muse, mutect2, varscan2
- FGF6 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as rs372807700; called by muse, varscan2
- FMN1 | c.2254C>T p.R752W (on ENST00000616417 / NM_001277313.2; = p.R529W on NM_001103184.4) | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1003249173, CM1514853, COSV57918440; called by muse, mutect2, varscan2
- GAD1 | c.673A>G p.M225V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.464); catalogued as COSV60151644; called by muse, mutect2, varscan2
- GPR137 | c.786G>A p.A262= | Splice Region (SNP) | VAF 110/133 reads (83%) | catalogued as rs369261653; called by muse, mutect2, varscan2
- GRM2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143196180; called by muse, mutect2, varscan2
- GRM5 | c.763C>A p.Q255K | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.192); catalogued as COSV100553329, COSV100554471; called by muse, mutect2, varscan2
- HTR1E | c.324C>A p.C108* | Nonsense Mutation (SNP) | VAF 59/107 reads (55%) | catalogued as COSV59506873; called by muse, mutect2, varscan2
- IGF2R | c.4056G>C p.L1352F | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1406224864, COSV63626726; called by muse, mutect2, varscan2
- INSYN1 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1470313482, COSV65837183; called by muse, mutect2, varscan2
- INTS2 | c.3220C>G p.L1074V | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52151145; called by muse, mutect2, varscan2
- JCAD | c.3050C>G p.A1017G | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV64758158, COSV64759952; called by muse, mutect2, varscan2
- KCNA5 | c.1619G>A p.G540D | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.055); catalogued as COSV52904086; called by muse, mutect2, varscan2
- KCNB2 | c.255C>G p.N85K | Missense Mutation (SNP) | VAF 96/200 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as COSV101578660, COSV73049080; called by muse, mutect2, varscan2
- KCND2 | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 56/64 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV58570645; called by muse, mutect2, varscan2
- KCNG1 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs944101242, COSV65368054; called by muse, mutect2, varscan2
- KCNMA1 | c.2966G>A p.R989H (on ENST00000286628 / NM_001161352.2; = p.R931H on NM_002247.4) | Missense Mutation (SNP) | VAF 128/312 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.321); catalogued as rs369646039; called by muse, mutect2, varscan2
- KIF17 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201078177, COSV56116101; called by muse, mutect2, varscan2
- KIRREL1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as rs370796550; called by muse, mutect2, varscan2
- KSR2 | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.229); catalogued as rs776051980, COSV56666620; called by muse, mutect2, varscan2
- LAMA1 | c.6323A>G p.Q2108R | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.299); catalogued as COSV67532758; called by muse, mutect2, varscan2
- LEFTY1 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55282311; called by muse, mutect2, varscan2
- LMO2 | c.242G>A p.R81Q (on ENST00000395833 / NM_001142315.2; = p.R150Q on NM_005574.4) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs111991485, COSV57645549; called by muse, mutect2, varscan2
- LRP2 | c.1913A>C p.Y638S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as COSV55542451; called by muse, mutect2, varscan2
- LRRK2 | c.3768A>C p.K1256N | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV54145189; called by muse, mutect2, varscan2
- LZTS3 | c.577C>G p.P193A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.189); catalogued as COSV61277081, COSV61277875; called by muse, mutect2, varscan2
- MAEA | c.470T>C p.I157T | Missense Mutation (SNP) | VAF 102/279 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV53261333; called by muse, mutect2, varscan2
- MAGEB4 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV66775262; called by muse, mutect2, varscan2
- MASTL | c.1645T>A p.L549I | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV60909604; called by muse, mutect2, varscan2
- MGAT4C | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.432); catalogued as COSV59830301; called by muse, mutect2, varscan2
- MMRN1 | c.1061A>C p.N354T | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV53334104; called by muse, mutect2, varscan2
- MTRF1 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53480806; called by muse, mutect2, varscan2
- MTUS2 | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV70914059; called by muse, mutect2, varscan2
- MUSK | c.1886T>C p.L629P | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51878939; called by muse, mutect2, varscan2
- MYCBP2 | c.10364C>A p.A3455E (on ENST00000357337; = p.A3493E on NM_015057.5) | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as COSV62011215; called by muse, mutect2, varscan2
- MYO10 | c.3106A>C p.M1036L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV57017345; called by muse, mutect2, varscan2
- MYO5A | c.2438G>T p.R813L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs561485938, COSV62557059, COSV62561239; called by muse, mutect2, varscan2
- NBEA | c.1529A>T p.D510V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59762903; called by muse, mutect2, varscan2
- NBEAL1 | c.6834+1G>A p.X2278_splice | Splice Site (SNP) | VAF 23/114 reads (20%) | catalogued as COSV58719620; called by muse, mutect2, varscan2
- NEGR1 | c.385A>C p.M129L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV60832204; called by muse, mutect2, varscan2
- NPHS2 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs200544576, COSV62634651; ClinVar: uncertain significance; called by muse, mutect2
- NRK | c.4348A>C p.K1450Q | Missense Mutation (SNP) | VAF 74/87 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV54590765; called by muse, mutect2, varscan2
- OLFM3 | c.257T>C p.L86P (on ENST00000338858 / NM_001288821.1; = p.L66P on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58796124, COSV58798328; called by muse, mutect2, varscan2
- OR10X1 | c.655T>C p.S219P | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV63766989; called by muse, mutect2, varscan2
- OR2T12 | c.877A>G p.S293G | Missense Mutation (SNP) | VAF 114/203 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV58776339; called by muse, mutect2, varscan2
- OR2Z1 | c.34T>A p.F12I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1402400964, COSV60691763; called by muse, mutect2, varscan2
- OR52I2 | c.492A>T p.R164S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs1380674571, COSV57044330; called by muse, mutect2, varscan2
- OR5D13 | c.274A>T p.R92* | Nonsense Mutation (SNP) | VAF 48/222 reads (22%) | catalogued as COSV62332827; called by muse, mutect2, varscan2
- PAK4 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs777017835, COSV58943876; called by muse, mutect2, varscan2
- PCDHB10 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 77/100 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53375757; called by muse, mutect2, varscan2
- PCLO | c.8021T>C p.V2674A | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV61617859; called by muse, mutect2, varscan2
- PCLO | c.5404A>G p.S1802G | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs572868112, COSV61617870; called by muse, mutect2, varscan2
- PLCL1 | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559099836, COSV70821454, COSV70821834; called by muse, mutect2, varscan2
- POSTN | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs200287900, COSV65711996; called by muse, mutect2, varscan2
- PPP1R3A | c.1402A>G p.K468E | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV52876012, COSV52877170; called by muse, mutect2, varscan2
- PPP4R2 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55594268; called by muse, mutect2, varscan2
- PSAPL1 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV59842377; called by muse, mutect2, varscan2
- PTPRU | c.3326G>A p.G1109D | Missense Mutation (SNP) | VAF 68/116 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60522594; called by muse, mutect2, varscan2
- RCN3 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54541242; called by muse, mutect2, varscan2
- RPAP1 | c.3757G>A p.V1253M | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs143725774; called by muse, mutect2, varscan2
- SAMD9L | c.4640C>A p.P1547Q | Missense Mutation (SNP) | VAF 84/118 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV59079843; called by muse, mutect2, varscan2
- SCML2 | c.10A>C p.T4P | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV52618780; called by muse, mutect2, varscan2
- SCN10A | c.1971T>G p.I657M | Missense Mutation (SNP) | VAF 60/102 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV104437300, COSV71860390; called by muse, mutect2, varscan2
- SHLD1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs140278441; called by muse, mutect2, varscan2
- SLC25A12 | c.759T>A p.F253L | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV55531657; called by muse, mutect2, varscan2
- SNTG2 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV57969808; called by muse, mutect2, varscan2
- SPANXN3 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 213/235 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV65140037; called by muse, mutect2, varscan2
- SPEF2 | c.5360A>G p.Y1787C | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.362); catalogued as COSV57427238; called by muse, mutect2, varscan2
- SPTAN1 | c.222C>G p.D74E | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.268); catalogued as COSV63985627; called by muse, mutect2, varscan2
- SRSF12 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs138061111, COSV101504959; called by muse, mutect2, varscan2
- SYBU | c.635A>C p.Q212P (on ENST00000276646 / NM_001099754.2; = p.Q211P on NM_017786.6) | Missense Mutation (SNP) | VAF 98/445 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52614639; called by muse, mutect2, varscan2
- TIE1 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as rs372583997, COSV100992102, COSV65248632, COSV65251719; called by muse, mutect2, varscan2
- TOM1 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776007349, COSV65897461; called by muse, mutect2, varscan2
- TRIML2 | c.1252A>C p.S418R | Missense Mutation (SNP) | VAF 87/107 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV58714802, COSV58718334; called by muse, mutect2, varscan2
- TRPS1 | c.3204A>G p.I1068M (on ENST00000220888 / NM_001330599.2; = p.I1081M on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/348 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55228083; called by muse, mutect2, varscan2
- TTC29 | c.1131T>G p.F377L | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57272145; called by muse, mutect2, varscan2
- TTN | c.48357A>C p.E16119D (on ENST00000591111; = p.E8695D on NM_003319.4) | Missense Mutation (SNP) | VAF 54/178 reads (30%) | PolyPhen benign (0.074); catalogued as COSV59905709; called by muse, mutect2, varscan2
- VCPIP1 | c.1489A>G p.S497G | Missense Mutation (SNP) | VAF 259/466 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60046103; called by muse, mutect2, varscan2
- VN1R2 | c.695C>A p.T232N | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV59037247; called by muse, mutect2, varscan2
- ZC3H4 | c.324G>C p.K108N | Missense Mutation (SNP) | VAF 111/463 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV53410800; called by muse, mutect2, varscan2
- ZFPM2 | c.1172T>G p.L391R | Missense Mutation (SNP) | VAF 48/475 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as COSV65872668; called by muse, mutect2, varscan2
- ZNF287 | c.190C>G p.R64G | Missense Mutation (SNP) | VAF 62/80 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67688160, COSV67688733; called by muse, mutect2, varscan2
- ZNF329 | c.953A>C p.N318T | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV63771767; called by muse, mutect2, varscan2
- ZNF33A | c.2092G>A p.G698R (on ENST00000458705 / NM_006974.3; = p.G699R on NM_006954.2) | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56723378; called by muse, mutect2, varscan2
- ZNF71 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV60146683; called by muse, mutect2, varscan2
- CNOT3 | c.2209_2211del p.K737del | In Frame Del (DEL) | VAF 10/22 reads (45%) | called by pindel, varscan2
- NKAPL | c.738dup p.E247Rfs*4 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.3778A>G p.R1260G | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by mutect2, varscan2
- ZNF267 | c.1083dup p.N362* | Frame Shift Ins (INS) | VAF 70/132 reads (53%) | called by mutect2, pindel, varscan2
- ADAMTS3 | c.3594A>C p.T1198= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV54385957; called by muse, mutect2, varscan2
- ADAMTSL3 | c.918T>G p.T306= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as COSV54437686; called by muse, mutect2, varscan2
- APOL2 | c.327C>T p.V109= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV50771866; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1572T>C p.I524= | Silent (SNP) | VAF 60/80 reads (75%) | catalogued as COSV52870984; called by muse, mutect2, varscan2
- ATRNL1 | c.1851T>C p.A617= | Silent (SNP) | VAF 77/158 reads (49%) | catalogued as COSV61797944; called by muse, mutect2, varscan2
- C3 | c.3057G>A p.T1019= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs749825273, COSV55568246; called by muse, mutect2, varscan2
- CA6 | c.390G>T p.G130= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV66261557, COSV66262006; called by muse, mutect2, varscan2
- CNTN3 | c.1323T>G p.S441= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV55164207; called by muse, mutect2, varscan2
- FKBP8 | c.87G>A p.G29= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV55891259; called by muse, mutect2, varscan2
- FLNA | c.1995C>T p.D665= | Silent (SNP) | VAF 119/134 reads (89%) | catalogued as rs368889011, COSV61038156; called by muse, mutect2, varscan2
- GLB1L2 | c.381C>T p.I127= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs371622365; called by muse, mutect2, varscan2
- GPR158 | c.1635T>G p.T545= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV66266005; called by muse, mutect2, varscan2
- IRF4 | c.807C>T p.S269= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as rs777806353, COSV66704520; called by muse, mutect2, varscan2
- KLHL4 | c.1107T>G p.S369= | Silent (SNP) | VAF 91/103 reads (88%) | catalogued as COSV64139442, COSV64143670; called by muse, mutect2, varscan2
- KMT2D | c.16171C>T p.L5391= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV56414141; called by muse, mutect2, varscan2
- NAP1L3 | c.960G>A p.K320= | Silent (SNP) | VAF 63/73 reads (86%) | catalogued as rs1222149850, COSV100220577, COSV59073888; called by muse, mutect2, varscan2
- NAV3 | c.2103C>A p.S701= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV57064231; called by muse, mutect2, varscan2
- NPPC | c.183C>T p.G61= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV54945202; called by muse, mutect2, varscan2
- NRG1 | c.144C>T p.S48= (on ENST00000523534; = p.S195= on NM_013962.2) | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV73057925; called by muse, mutect2, varscan2
- OCA2 | c.861G>C p.V287= | Silent (SNP) | VAF 62/146 reads (42%) | catalogued as COSV62339532; called by muse, mutect2, varscan2
- OR2G2 | c.834T>C p.S278= | Silent (SNP) | VAF 104/191 reads (54%) | catalogued as rs752329312, COSV60739537; called by muse, mutect2, varscan2
- OR5T3 | c.108A>G p.Q36= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV100282856, COSV57379534; called by muse, mutect2, varscan2
- OR7D4 | c.525G>A p.P175= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs111293642; called by muse, mutect2, varscan2
- PCDH8 | c.2295C>T p.A765= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV58810995; called by muse, mutect2, varscan2
- PCOLCE | c.756C>A p.L252= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV56159435; called by muse, mutect2, varscan2
- PTPRC | c.3157A>C p.R1053= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV61407126; called by muse, mutect2, varscan2
- PTPRD | c.4338A>G p.Q1446= | Silent (SNP) | VAF 106/232 reads (46%) | catalogued as rs919140762, COSV61930496; called by muse, mutect2, varscan2
- REM1 | c.153C>T p.S51= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs1457755856, COSV52426958; called by muse, mutect2, varscan2
- ROBO1 | c.4873A>C p.R1625= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV71392048, COSV71392271; called by muse, mutect2, varscan2
- SCN5A | c.891C>T p.D297= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs529144420, COSV61116995; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDK1 | c.1863G>A p.T621= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as rs375345968; called by muse, mutect2, varscan2
- SLC26A4 | c.1752G>A p.A584= | Silent (SNP) | VAF 39/50 reads (78%) | catalogued as rs771015634, COSV55914542; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPATA31A1 | c.1620T>C p.T540= | Silent (SNP) | VAF 87/332 reads (26%) | catalogued as rs1403834381; called by muse, mutect2, varscan2
- STOX1 | c.945C>G p.L315= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as rs763530730, COSV53813167; called by muse, mutect2, varscan2
- TMC4 | c.2064A>G p.R688= (on ENST00000617472 / NM_001145303.3; = p.R682= on NM_144686.4) | Silent (SNP) | VAF 48/90 reads (53%) | catalogued as COSV55360482; called by muse, mutect2, varscan2
- TMEM215 | c.315G>A p.K105= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as COSV61363197; called by muse, mutect2, varscan2
- TNN | c.1659G>A p.P553= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs147951218; called by muse, mutect2, varscan2
- TRRAP | c.8013G>A p.A2671= (on ENST00000359863 / NM_001244580.1; = p.A2653= on NM_003496.3) | Silent (SNP) | VAF 57/132 reads (43%) | catalogued as rs202052450, COSV62839819; called by muse, mutect2, varscan2
- ZMIZ1 | c.858G>A p.A286= | Silent (SNP) | VAF 87/184 reads (47%) | catalogued as rs770161889, COSV57890362; called by muse, mutect2, varscan2
- ZNF25 | c.1032T>C p.C344= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as rs764854368, COSV56921860; called by muse, mutect2, varscan2
- ZNF347 | c.1191A>G p.G397= | Silent (SNP) | VAF 72/129 reads (56%) | catalogued as rs145023051; called by muse, mutect2, varscan2
- ZNF471 | c.1878T>G p.P626= | Silent (SNP) | VAF 48/94 reads (51%) | catalogued as COSV57290004; called by muse, mutect2, varscan2
- CPLANE1 | c.*2755A>C | 3'UTR (SNP) | VAF 29/128 reads (23%) | catalogued as COSV57052509, COSV57053408; called by muse, mutect2, varscan2
- ERCC6 | c.-2G>C | 5'UTR (SNP) | VAF 42/84 reads (50%) | catalogued as rs1000658131, COSV100876197; called by muse, mutect2, varscan2
- FOLH1B | n.2059G>T | RNA (SNP) | VAF 112/133 reads (84%) | called by muse, mutect2, varscan2
- OR5V1 | c.*2C>T | 3'UTR (SNP) | VAF 41/87 reads (47%) | catalogued as COSV101011468; called by muse, mutect2, varscan2
